Somatic mutation profile of tumor specimen C3L-02747-02 (aliquot CPT0188480007) from CPTAC case C3L-02747, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 66.7 years (24,345 days).
Specimen C3L-02747-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 693a3fbd-912e-4745-9780-f6861e4fd4a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02747-31 (Blood Derived Normal), aliquot CPT0183170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbe6453f-503d-4d9e-8c5e-30f8fd22dc3b

The open-access MAF lists 91 somatic variants for this specimen: 68 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 14, Frame Shift Del 5, Intron 4, Frame Shift Ins 3, Nonsense Mutation 3, 3'UTR 3, 3'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 39/434 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2
- DYRK1A | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 74/286 reads (26%) | catalogued as rs724159948, CM1510734, COSV100117315; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 77/313 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 151/406 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.3113G>A p.R1038Q | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as rs1404359662, COSV59194465; called by muse, mutect2, varscan2
- ALDH1A2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1179037754, COSV99990713; called by muse, mutect2
- ARHGAP22 | c.910A>G p.S304G | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1299405171; called by muse, varscan2
- ARVCF | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs559641138; called by muse, mutect2, varscan2
- ASB9 | c.605C>A p.P202Q | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66851669; called by mutect2, varscan2
- BCL11B | c.1223C>T p.P408L (on ENST00000357195 / NM_001282237.2; = p.P337L on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1452791078, COSV100596021, COSV61735906; called by muse, varscan2
- CAPRIN1 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 35/378 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.997); catalogued as rs200525721; called by muse, mutect2
- CDH19 | c.305T>C p.I102T | Missense Mutation (SNP) | VAF 20/356 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1288826427; called by muse, mutect2
- CDHR2 | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs201059035; called by muse, mutect2, varscan2
- CHD4 | c.2590C>T p.R864W (on ENST00000357008 / NM_001363606.2; = p.R877W on NM_001273.5) | Missense Mutation (SNP) | VAF 78/306 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58898273; called by muse, mutect2, varscan2
- CUL3 | c.493_494del p.L165Ifs*37 | Frame Shift Del (DEL) | VAF 34/182 reads (19%) | catalogued as rs1553523940; called by pindel, varscan2
- DDR1 | c.2056C>T p.R686W (on ENST00000324771; = p.R649W on NM_001954.4) | Missense Mutation (SNP) | VAF 65/286 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747290299, COSV61319065; called by muse, mutect2, varscan2
- GRIN3A | c.1456G>A p.G486R | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs369373527; called by muse, mutect2, varscan2
- H1-8 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs1039574342, COSV100180372; called by muse, mutect2, varscan2
- IRX2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 99/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57411933; called by muse, mutect2, varscan2
- MBD1 | c.1106G>T p.R369L (on ENST00000269468 / NM_001323950.1; = p.R346L on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/480 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53998423, COSV54003378, COSV99497025; called by muse, mutect2, varscan2
- NPAP1 | c.2485C>A p.P829T | Missense Mutation (SNP) | VAF 78/347 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs757750807, COSV100275679; called by muse, mutect2, varscan2
- NRXN3 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 43/324 reads (13%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.955); catalogued as rs544312796; called by muse, mutect2, varscan2
- NSD1 | c.5375G>T p.G1792V | Missense Mutation (SNP) | VAF 54/570 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM030077; called by muse, mutect2
- OPHN1 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62783116; called by muse, mutect2
- OR51B6 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as rs751616967; called by muse, mutect2, varscan2
- OR9Q2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.005); catalogued as rs1455959865, COSV61111863, COSV61112062; called by muse, mutect2, varscan2
- OTUD6A | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as rs754807874, COSV57972961; called by muse, mutect2
- PIP | c.380C>A p.A127D | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780595639, COSV52120574; called by muse, mutect2, varscan2
- PKD1L1 | c.5420G>A p.R1807Q | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs771122484; called by muse, mutect2, varscan2
- PRDM7 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 43/412 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs771949203; called by muse, mutect2, varscan2
- PTGIS | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 113/498 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs745642215, COSV54836304; called by muse, mutect2, varscan2
- RAD9A | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.257); catalogued as rs746014328; called by muse, mutect2, varscan2
- RERE | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 120/465 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.343); catalogued as rs1220737626, COSV61946140; called by muse, mutect2, varscan2
- RNF112 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.997); catalogued as rs1162296009; called by muse, mutect2
- RTF1 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 48/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746938646; called by muse, mutect2, varscan2
- SETD2 | c.6071G>C p.R2024P | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57433930, COSV57435267; called by muse, mutect2, varscan2
- SPTBN5 | c.6670G>A p.G2224R | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as rs775843463; called by muse, mutect2, varscan2
- TENM4 | c.4489G>A p.V1497I | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.97); catalogued as rs868125910; called by muse, mutect2, varscan2
- TP53 | c.994del p.I332Sfs*13 | Frame Shift Del (DEL) | VAF 76/363 reads (21%) | catalogued as COSV52849382, COSV53175834, COSV99400287; called by mutect2, pindel, varscan2
- WFIKKN1 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 64/297 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs200981073; called by muse, mutect2, varscan2
- ABHD5 | c.524T>C p.L175S | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADGRG2 | c.2509G>T p.G837C (on ENST00000379869 / NM_001079858.3; = p.G834C on NM_005756.4) | Missense Mutation (SNP) | VAF 38/414 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARHGAP22 | c.941_945del p.P314Hfs*290 | Frame Shift Del (DEL) | VAF 71/360 reads (20%) | called by pindel, varscan2
- ATRX | c.5261A>C p.N1754T | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BICD2 | c.1493T>C p.L498P | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- DNHD1 | c.5122C>A p.L1708M | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EHD2 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ESRRB | c.1192C>G p.L398V | Missense Mutation (SNP) | VAF 130/584 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM155B | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC8 | c.872T>A p.I291N | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2
- HNRNPH3 | c.244G>A p.G82R | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.866); called by muse, mutect2
- HSPG2 | c.9442dup p.R3148Pfs*29 | Frame Shift Ins (INS) | VAF 53/267 reads (20%) | called by mutect2, pindel, varscan2
- IHH | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- JMJD1C | c.3973_3981del p.S1325_D1327del | In Frame Del (DEL) | VAF 32/154 reads (21%) | called by mutect2, pindel, varscan2
- KIAA1109 | c.5539A>G p.I1847V | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- KIF22 | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KIF3B | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 62/275 reads (23%) | called by muse, mutect2, varscan2
- LRIF1 | c.1757G>T p.R586L | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- NAAA | c.1076A>C p.K359T | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1747G>T p.A583S (on ENST00000259318 / NM_001136562.3; = p.A814S on NM_007203.5) | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDS5B | c.3416C>G p.S1139* | Nonsense Mutation (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- PGR | c.2028_2029insAA p.P677Nfs*8 | Frame Shift Ins (INS) | VAF 42/245 reads (17%) | called by mutect2, pindel, varscan2
- PGR | c.1768T>G p.F590V | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- REV3L | c.4738_4739dup p.R1581Qfs*22 | Frame Shift Ins (INS) | VAF 67/334 reads (20%) | called by mutect2, pindel, varscan2
- RMI1 | c.850del p.S284Vfs*23 | Frame Shift Del (DEL) | VAF 32/161 reads (20%) | called by mutect2, pindel, varscan2
- TNFRSF1B | c.1223_1224del p.T408Rfs*47 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by pindel, varscan2
- TTN | c.9052A>T p.T3018S (on ENST00000591111; = p.T2972S on NM_003319.4) | Missense Mutation (SNP) | VAF 27/401 reads (7%) | PolyPhen benign (0.034); called by muse, mutect2
- ZBTB33 | c.549C>G p.I183M | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- ADCY3 | c.2823C>T p.I941= | Silent (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- ALLC | c.1065C>T p.D355= | Silent (SNP) | VAF 50/262 reads (19%) | catalogued as rs1479932817, COSV52993134; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2217C>T p.D739= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as rs1280129373; called by muse, mutect2
- CAMK2B | c.1653C>T p.N551= | Silent (SNP) | VAF 58/344 reads (17%) | catalogued as rs1255161110; called by muse, mutect2, varscan2
- DISP3 | c.570C>T p.S190= | Silent (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2
- GDA | c.768C>A p.P256= | Silent (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- HES2 | c.189C>T p.T63= | Silent (SNP) | VAF 77/402 reads (19%) | catalogued as rs1374735328; called by muse, mutect2, varscan2
- MXRA5 | c.5772C>T p.G1924= | Silent (SNP) | VAF 18/289 reads (6%) | called by muse, mutect2
- PCBP3 | c.447C>T p.G149= | Silent (SNP) | VAF 47/276 reads (17%) | called by muse, mutect2, varscan2
- QRFP | c.264C>T p.F88= | Silent (SNP) | VAF 77/324 reads (24%) | catalogued as rs377616366; called by muse, mutect2, varscan2
- RIMKLA | c.546C>T p.H182= | Silent (SNP) | VAF 71/369 reads (19%) | catalogued as rs778321428, COSV68909976; called by muse, mutect2, varscan2
- SETD1B | c.4977G>A p.S1659= | Silent (SNP) | VAF 39/176 reads (22%) | catalogued as rs1312614521; called by muse, mutect2, varscan2
- SH3GL1 | c.1077C>T p.Y359= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as rs758130730, COSV53656082; called by muse, mutect2, varscan2
- TPP2 | c.1191A>G p.S397= | Silent (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- AC091163.2 | n.460-448T>C | Intron (SNP) | VAF 32/419 reads (8%) | catalogued as rs773322309; called by muse, mutect2
- ATP11C | c.*65A>C | 3'UTR (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- ATP11C | c.*64T>A | 3'UTR (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- FAM104B | c.20+37C>T | Intron (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- GAMT | c.*14C>G | 3'UTR (SNP) | VAF 52/216 reads (24%) | catalogued as COSV52040930; called by muse, mutect2, varscan2
- SEC1P | n.621A>G | RNA (SNP) | VAF 106/474 reads (22%) | called by muse, mutect2, varscan2
- SHANK2 | c.1108-56219G>A | Intron (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- SNRNP40 | c.776-44G>A | Intron (SNP) | VAF 18/73 reads (25%) | catalogued as rs759328614; called by muse, mutect2, varscan2
- TMEM161B | chr5:88190093 G>A | 3'Flank (SNP) | VAF 24/218 reads (11%) | catalogued as rs1044454376; called by muse, mutect2, varscan2
